TCGA case TCGA-RQ-A6JB — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Bones, joints and articular cartilage of other and unspecified sites; Tissue source site: St. Joseph's Hospital AZ. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dc87a809-95de-4eb7-a1c2-2650475f2d7e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Primary diffuse large B-cell lymphoma of the CNS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Bones of skull and face and associated joints; Site of resection or biopsy: Bones of skull and face and associated joints; Classification of tumor: primary; Age at diagnosis: 62.6 years (22,859 days); Year of diagnosis: 2011; AJCC staging edition: 7th; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1 day; Ann Arbor extranodal involvement: Yes; Sites of involvement: Lymph node, NOS / Bone, NOS / Skin / Soft tissue.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Consistent pathology review: Yes.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 167 cm; BMI: 25.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RQ-A6JB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 370 mg.
  Slide TCGA-RQ-A6JB-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-RQ-A6JB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RQ-A6JB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Primary DLBCL of the CNS; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: HIV status: Negative.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 3.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Bone; Submitted tumor site: Skin; Submitted tumor site: Soft Tissue (muscle  ligaments  subcutaneous).
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1 days; disease-specific survival: no event (censored), 1 days; progression-free interval: no event (censored), 1 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RQ-A6JB-01A-11D-A31W-01): tumor purity 0.72, ploidy 1.98, whole-genome doublings 0.
